Gene-level copy-number profile of tumor specimen ALCH-B2CM-TTP1-A from ALCHEMIST case ALCH-B2CM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.4 years (20,966 days).
Specimen ALCH-B2CM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9323fe18-c0fb-4ac6-8984-6442cd8491ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2CM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/6734d9f0-20b6-4912-bd0d-2f998b722362

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 3,538; copy number 2: 52,646; copy number 3: 2,028; copy number 4: 60; copy number 5: 68; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,114,838–90,115,402, 1 gene (within-gene range 0–1): IGKV3D-15.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr2:91,617,160–91,723,605, 5 genes (within-gene range 0–1): LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2.
- chr3:47,413,681–47,580,792, 6 genes: SCAP, AC099778.2, ELP6, BOLA2P2, RN7SL870P, CSPG5.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr5:134,399,495–134,423,335, 3 genes: AC109454.2, CDKN2AIPNL, AC109454.1.
- chr7:99,442,890–99,443,496, 1 gene (within-gene range 0–1): AC073063.1.
- chr7:99,504,662–99,534,700, 1 gene: ZKSCAN5.
- chr8:123,178,960–123,210,079, 5 genes: FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:74,744,386–74,744,707, 1 gene: FAM32CP.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr12:38,155,476–38,167,631, 3 genes: AC079460.2, RNA5SP358, RNA5SP359.
- chr16:46,850,999–46,851,254, 1 gene: AC007225.2.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr17:22,090,743–22,205,154, 1 gene: UBBP4.
- chr17:75,498,548–75,498,628, 1 gene (within-gene range 0–2): MIR6785.
- chr19:3,594,507–3,606,875, 1 gene: TBXA2R.
- chr19:38,108,500–38,109,533, 1 gene (within-gene range 0–2): AC011465.1.
- chr19:38,251,237–38,256,532, 1 gene (within-gene range 0–1): PPP1R14A.
- chr22:17,256,859–17,266,733, 1 gene: CECR3.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 71 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:9,018,293–9,018,899, 1 gene, copy number 5: HMGB1P25.
- chr6:32,578,769–32,589,848, 1 gene, copy number 5: HLA-DRB1.
- chr7:43,608,456–43,729,717, 1 gene, copy number 5 (within-gene range 2–5): COA1.
- chr7:74,650,231–74,760,692, 3 genes, copy number 5: GTF2I, AC211433.1, PHBP15.
- chr10:22,534,854–22,714,578, 2 genes, copy number 5: PIP4K2A, AL390318.1.
- chr12:68,552,995–70,920,738, 55 genes, copy number 5 (within-gene range 3–5): RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr14:105,583,731–105,601,728, 2 genes, copy number 6 (within-gene range 0–6): IGHA2, IGHE.
- chr15:77,984,036–78,077,724, 1 gene, copy number 6 (within-gene range 1–6): TBC1D2B.
- chr19:1,852,382–1,863,579, 3 genes, copy number 5: AC012615.3, KLF16, AC012615.4.
- chr19:3,572,777–3,579,088, 1 gene, copy number 5 (within-gene range 2–5): HMG20B.
- chr22:18,715,815–18,719,341, 1 gene, copy number 5: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 3,096. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
